Somatic mutation profile of tumor specimen C3N-01846-01 (aliquot CPT0098770009) from CPTAC case C3N-01846, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 69.9 years (25,518 days).
Specimen C3N-01846-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 19a96b64-3421-486a-a126-28594b9c56d8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01846-31 (Blood Derived Normal), aliquot CPT0098810002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/454e00dd-d304-4f14-beac-fd0a9d2314dc

The open-access MAF lists 174 somatic variants for this specimen: 124 protein-altering or splice-affecting, 32 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 32, Intron 11, Nonsense Mutation 7, Frame Shift Del 4, Splice Site 3, 5'UTR 3, RNA 2, Frame Shift Ins 2, 3'UTR 2, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.814G>T p.V272L | Missense Mutation (SNP) | VAF 201/425 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs121912657, CM130241, CM920676, COSV52661812, COSV52677483, COSV52701127; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC3 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV53329533; called by muse, mutect2
- AHDC1 | c.2233C>T p.R745W | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99899869; called by muse, mutect2, varscan2
- AMBP | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as rs537004728, COSV54323449; called by muse, mutect2, varscan2
- ANK3 | c.12037C>T p.R4013C | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.996); catalogued as rs755321457, COSV55068312; called by muse, mutect2, varscan2
- ARHGAP4 | c.415G>A p.V139M | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs782707429; called by muse, mutect2, varscan2
- ASH1L | c.7330C>T p.R2444C (on ENST00000368346 / NM_001366177.2; = p.R2439C on NM_018489.3) | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs766745788; called by muse, mutect2, varscan2
- ASMTL | c.641C>T p.P214L | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.814); catalogued as rs1158958372, COSV101187732, COSV67242736; called by muse, mutect2
- BUB1B | c.3007G>A p.A1003T | Missense Mutation (SNP) | VAF 27/204 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as rs1222026369; called by muse, mutect2, varscan2
- CARMIL1 | c.2398C>T p.R800* | Nonsense Mutation (SNP) | VAF 15/189 reads (8%) | catalogued as rs1185105289, COSV61515828; called by muse, mutect2
- CCDC60 | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.564); catalogued as rs1203457987, COSV59551015; called by muse, mutect2
- CCN5 | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.701); catalogued as COSV51938216; called by muse, mutect2
- CDH12 | c.368C>T p.P123L | Missense Mutation (SNP) | VAF 52/583 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.885); catalogued as rs1428435649, COSV101202564, COSV66419690; called by muse, mutect2
- CELSR3 | c.3352G>A p.D1118N | Missense Mutation (SNP) | VAF 76/190 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs759571026; called by muse, mutect2, varscan2
- CHRNA1 | c.935C>A p.T312K (on ENST00000261007 / NM_001039523.3; = p.T287K on NM_000079.4) | Missense Mutation (SNP) | VAF 66/263 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53685756; called by muse, mutect2, varscan2
- CHST13 | c.736C>G p.H246D | Missense Mutation (SNP) | VAF 74/245 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60042808; called by muse, mutect2, varscan2
- COL1A2 | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 30/549 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM141560; called by muse, mutect2
- COL20A1 | c.129G>C p.Q43H | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV58914105; called by muse, mutect2, varscan2
- CPS1 | c.2117C>A p.T706N | Missense Mutation (SNP) | VAF 36/213 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.043); catalogued as COSV51824092; called by muse, mutect2, varscan2
- DMD | c.8535C>G p.N2845K | Missense Mutation (SNP) | VAF 88/167 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.106); catalogued as rs1302775057, COSV58945433; called by muse, mutect2, varscan2
- DNAH5 | c.6422G>T p.C2141F | Missense Mutation (SNP) | VAF 56/276 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763231103; called by muse, mutect2, varscan2
- ERBB3 | c.3701C>G p.S1234C | Missense Mutation (SNP) | VAF 16/376 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.319); catalogued as COSV57247135, COSV57248025, COSV57256413; called by muse, mutect2
- EXD1 | c.847C>A p.R283S | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.253); catalogued as COSV59257064; called by muse, mutect2
- GJC2 | c.1270G>A p.E424K | Missense Mutation (SNP) | VAF 41/234 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.259); catalogued as rs1226560267; called by muse, mutect2, varscan2
- HECTD3 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 33/262 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as COSV64670065; called by muse, mutect2, varscan2
- IFRD2 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 85/194 reads (44%) | catalogued as COSV100269376; called by muse, mutect2, varscan2
- IMPDH2 | c.215_216del p.T72Sfs*26 | Frame Shift Del (DEL) | VAF 44/231 reads (19%) | catalogued as rs1197979218; called by pindel, varscan2
- IRX1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 26/636 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57361689; called by muse, mutect2
- JPH2 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs1161637704; called by muse, mutect2
- KRBA2 | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 82/175 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.095); catalogued as rs767349566; called by muse, mutect2, varscan2
- LIG4 | c.52G>A p.D18N | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.221); catalogued as rs750736898; called by muse, varscan2
- LMLN | c.1645G>A p.G549R | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1168840498, COSV57605335; called by muse, mutect2
- MAGEB10 | c.131C>A p.A44D | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV63311780; called by muse, mutect2, varscan2
- MKRN3 | c.382A>T p.T128S | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV100091282; called by muse, mutect2, varscan2
- MTM1 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs145204414, COSV60335664; called by muse, mutect2, varscan2
- MYF6 | c.530C>A p.A177E | Missense Mutation (SNP) | VAF 71/251 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs770081936, COSV57353849; called by muse, mutect2, varscan2
- NOP14 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251960945; called by muse, mutect2, varscan2
- OR51V1 | c.494G>T p.C165F | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT tolerated (0.61); PolyPhen benign (0.158); catalogued as rs1409833193; called by muse, mutect2, varscan2
- OR5B12 | c.755C>A p.T252K | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); catalogued as COSV100222367; called by muse, mutect2, varscan2
- OTOG | c.8438C>A p.T2813N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV61133467; called by muse, mutect2, varscan2
- PCDH15 | c.2894A>G p.Y965C | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777290002, COSV100225578; called by muse, mutect2, varscan2
- PEG3 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs771803012, COSV55651668, COSV99689622; called by muse, mutect2, varscan2
- RBP4 | c.205G>A p.G69S | Missense Mutation (SNP) | VAF 41/283 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs761838369, COSV101012311; called by muse, mutect2, varscan2
- SHROOM3 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 8/77 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV56026051; called by muse, mutect2, varscan2
- SLC25A12 | c.737T>C p.V246A | Missense Mutation (SNP) | VAF 25/321 reads (8%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs755954046; ClinVar: uncertain significance; called by muse, mutect2
- TGFBR1 | c.1190A>G p.K397R | Missense Mutation (SNP) | VAF 78/282 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.87); catalogued as rs907536931; called by muse, mutect2, varscan2
- TMPRSS15 | c.1987G>C p.D663H | Missense Mutation (SNP) | VAF 81/215 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99518900; called by muse, mutect2, varscan2
- TSNAX | c.418C>T p.R140* | Nonsense Mutation (SNP) | VAF 35/255 reads (14%) | catalogued as rs750263571, COSV100791125; called by muse, mutect2, varscan2
- VEGFD | c.422G>T p.R141L | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52910532; called by muse, mutect2, varscan2
- WDR87 | c.6230T>A p.L2077* | Nonsense Mutation (SNP) | VAF 40/187 reads (21%) | catalogued as rs1488039835; called by muse, mutect2, varscan2
- ZFHX4 | c.6833G>T p.R2278L | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51499657, COSV99265627; called by muse, mutect2, varscan2
- ZNF717 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 25/263 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs770675173; called by muse, mutect2
- ADAMTS18 | c.3203G>T p.C1068F | Missense Mutation (SNP) | VAF 62/286 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRG7 | c.2213dup p.S739Ifs*23 | Frame Shift Ins (INS) | VAF 38/220 reads (17%) | called by mutect2, pindel, varscan2
- ADGRL2 | c.2276A>G p.N759S (on ENST00000370717 / NM_001366005.1; = p.N746S on NM_012302.4) | Missense Mutation (SNP) | VAF 59/213 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- AP3D1 | c.1094A>T p.Y365F | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ASPM | c.5306A>T p.Q1769L | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- BICC1 | c.1424T>G p.L475W | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BLCAP | c.140_142dup p.A47_L48insS | In Frame Ins (INS) | VAF 69/385 reads (18%) | called by mutect2, pindel, varscan2
- CACNA1E | c.6158G>A p.S2053N (on ENST00000367573 / NM_001205293.3; = p.S2010N on NM_000721.4) | Missense Mutation (SNP) | VAF 20/133 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); called by muse, mutect2, varscan2
- CACNA2D4 | c.457C>G p.L153V | Missense Mutation (SNP) | VAF 50/180 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.673); called by muse, mutect2, varscan2
- CCDC173 | c.1528G>T p.V510L | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.013); called by muse, mutect2
- CCDC27 | c.379G>T p.V127F | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.154); called by muse, mutect2
- CCR2 | c.281C>T p.T94I | Missense Mutation (SNP) | VAF 24/164 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD86 | c.948T>A p.S316R (on ENST00000330540 / NM_175862.5; = p.S310R on NM_006889.4) | Missense Mutation (SNP) | VAF 101/304 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- CENPF | c.3725G>C p.R1242T | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- CES5A | c.1125+1G>T p.X375_splice | Splice Site (SNP) | VAF 47/138 reads (34%) | called by muse, mutect2, varscan2
- COL11A1 | c.3439-1G>T p.X1147_splice | Splice Site (SNP) | VAF 41/177 reads (23%) | called by muse, mutect2, varscan2
- CWH43 | c.137G>C p.S46T | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CYP2D6 | c.827T>C p.L276P | Missense Mutation (SNP) | VAF 50/562 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- DDR1 | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- DDX21 | c.1109_1124del p.Q370Lfs*16 | Frame Shift Del (DEL) | VAF 22/119 reads (18%) | called by mutect2, pindel, varscan2
- DSG4 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 75/315 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DYTN | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 41/258 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- EEF1AKNMT | c.1748T>A p.L583Q (on ENST00000361735 / NM_015935.5; = p.L497Q on NM_014955.3) | Missense Mutation (SNP) | VAF 159/328 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- EFCAB7 | c.355G>A p.D119N | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ELFN2 | c.2313G>T p.E771D | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- FBXL4 | c.1370G>T p.S457I | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- GNAZ | c.1035A>G p.I345M | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); called by muse, mutect2
- GPATCH2 | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRIP1 | c.1334A>T p.K445M (on ENST00000359742 / NM_001379345.1; = p.K393M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/206 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- GYS1 | c.1645G>T p.G549C | Missense Mutation (SNP) | VAF 49/221 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HS6ST2 | c.768C>A p.C256* | Nonsense Mutation (SNP) | VAF 35/73 reads (48%) | called by muse, mutect2, varscan2
- IL16 | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 27/188 reads (14%) | called by muse, mutect2, varscan2
- ITGA2 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 69/202 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- KDM3A | c.746T>A p.V249E | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- KDM4A | c.3122G>A p.R1041Q | Missense Mutation (SNP) | VAF 16/152 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KLHL4 | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRTAP10-6 | c.974C>A p.A325D | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LAMA3 | c.8774G>A p.G2925E (on ENST00000313654 / NM_198129.4; = p.G1316E on NM_000227.6) | Missense Mutation (SNP) | VAF 62/384 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LMBRD1 | c.368A>G p.Y123C | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- LPCAT2 | c.317T>C p.I106T | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2
- MRPL43 | c.245G>T p.G82V | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC19 | c.347G>C p.G116A | Missense Mutation (SNP) | VAF 18/118 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MYO10 | c.2627G>T p.R876L | Missense Mutation (SNP) | VAF 39/235 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAV3 | c.535T>A p.L179I | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- NR0B1 | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 103/166 reads (62%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- OR2Z1 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 97/221 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PCBP1 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 140/393 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- PDF | c.254C>A p.A85E | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PEX1 | c.2914G>C p.E972Q | Missense Mutation (SNP) | VAF 78/576 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHTF1 | c.512G>C p.G171A | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- PSKH2 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- PXK | c.784C>T p.L262F | Missense Mutation (SNP) | VAF 40/129 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- RBFOX1 | c.257C>G p.S86C | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- RCVRN | c.577G>T p.V193L | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- RRAGB | c.378-1G>T p.X126_splice (on ENST00000262850 / NM_016656.4; = p.X98_splice on NM_006064.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 26/57 reads (46%) | called by muse, varscan2
- SALL3 | c.2088G>A p.M696I | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SEZ6L | c.1210G>A p.V404I | Missense Mutation (SNP) | VAF 37/73 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC12A1 | c.928G>A p.V310M | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); called by muse, varscan2
- SLC39A7 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLCO1B1 | c.1714C>G p.L572V | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLIT3 | c.3573C>A p.D1191E | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.22); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- SPATA16 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 272/1086 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, varscan2
- TAOK2 | c.682del p.M228* | Frame Shift Del (DEL) | VAF 22/241 reads (9%) | called by mutect2, pindel
- TBXT | c.59T>C p.L20P | Missense Mutation (SNP) | VAF 60/251 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TENM1 | c.7880G>C p.G2627A | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); called by muse, mutect2, varscan2
- TMEM65 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMPPE | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TRIM37 | c.1170G>C p.L390F | Missense Mutation (SNP) | VAF 125/229 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM49 | c.1156del p.D386Tfs*24 | Frame Shift Del (DEL) | VAF 79/282 reads (28%) | called by mutect2, pindel, varscan2
- TSC2 | c.2372dup p.C791Wfs*27 | Frame Shift Ins (INS) | VAF 49/146 reads (34%) | called by mutect2, pindel, varscan2
- VPS4A | c.439A>G p.I147V | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- XPNPEP1 | c.243T>G p.H81Q | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP9B | c.2947C>T p.L983= | Silent (SNP) | VAF 26/113 reads (23%) | called by muse, mutect2, varscan2
- BHMT2 | c.957C>T p.H319= | Silent (SNP) | VAF 35/174 reads (20%) | catalogued as rs140286658; called by muse, mutect2, varscan2
- DISP3 | c.1122C>T p.H374= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs761876206, COSV99609308; called by muse, mutect2, varscan2
- FAM81B | c.522C>A p.L174= | Silent (SNP) | VAF 25/73 reads (34%) | called by muse, varscan2
- FLNB | c.6351G>T p.L2117= | Silent (SNP) | VAF 32/252 reads (13%) | called by muse, mutect2, varscan2
- FOXD2 | c.939C>A p.G313= | Silent (SNP) | VAF 37/192 reads (19%) | called by muse, mutect2, varscan2
- FOXE3 | c.630C>A p.P210= | Silent (SNP) | VAF 17/132 reads (13%) | called by muse, mutect2, varscan2
- IGLV1-40 | c.72G>T p.T24= | Silent (SNP) | VAF 15/136 reads (11%) | catalogued as rs544091649; called by muse, mutect2, varscan2
- IQSEC3 | c.1140G>C p.P380= (on ENST00000538872 / NM_001170738.2; = p.P77= on NM_015232.1) | Silent (SNP) | VAF 41/172 reads (24%) | called by muse, mutect2, varscan2
- KCNQ2 | c.2007G>A p.P669= (on ENST00000359125 / NM_172107.4; = p.P641= on NM_004518.6) | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs542053755, COSV60539460; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAPK4 | c.1593C>A p.G531= | Silent (SNP) | VAF 23/104 reads (22%) | called by muse, mutect2, varscan2
- MUC12 | c.11025A>G p.T3675= (on ENST00000379442; = p.T3532= on NM_001164462.1) | Silent (SNP) | VAF 136/721 reads (19%) | catalogued as rs1399165465; called by muse, mutect2, varscan2
- MYH15 | c.2745G>A p.E915= | Silent (SNP) | VAF 14/138 reads (10%) | catalogued as rs750824388; called by muse, mutect2
- NMBR | c.573T>C p.D191= | Silent (SNP) | VAF 48/183 reads (26%) | called by muse, mutect2, varscan2
- PLXNA3 | c.2970T>G p.P990= | Silent (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- PPP6R1 | c.1575C>T p.H525= | Silent (SNP) | VAF 41/117 reads (35%) | catalogued as rs1431891881, COSV69800713; called by muse, mutect2, varscan2
- PRDM7 | c.811C>T p.L271= | Silent (SNP) | VAF 88/333 reads (26%) | called by muse, mutect2, varscan2
- RGS20 | c.306G>A p.L102= | Silent (SNP) | VAF 10/124 reads (8%) | catalogued as COSV99392460; called by muse, mutect2
- ROPN1 | c.177C>T p.V59= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as rs1408872532; called by muse, mutect2, varscan2
- SAGE1 | c.2649G>A p.E883= | Silent (SNP) | VAF 56/107 reads (52%) | called by muse, mutect2, varscan2
- SHOX | c.573A>G p.L191= | Silent (SNP) | VAF 126/346 reads (36%) | called by muse, mutect2, varscan2
- SLC17A3 | c.1242G>A p.E414= | Silent (SNP) | VAF 36/205 reads (18%) | called by muse, mutect2, varscan2
- SMC5 | c.429A>C p.A143= | Silent (SNP) | VAF 31/93 reads (33%) | called by muse, mutect2, varscan2
- SPEM2 | c.714T>C p.P238= | Silent (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
- SSC5D | c.1620C>T p.T540= | Silent (SNP) | VAF 16/348 reads (5%) | catalogued as rs1052226850, COSV101047336; called by muse, mutect2
- SSTR2 | c.942C>T p.F314= | Silent (SNP) | VAF 14/182 reads (8%) | catalogued as rs1165831803; called by muse, mutect2
- TEAD4 | c.315G>A p.L105= | Silent (SNP) | VAF 36/198 reads (18%) | called by muse, mutect2, varscan2
- THAP9 | c.117C>T p.I39= | Silent (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- ZNF114 | c.564G>A p.P188= | Silent (SNP) | VAF 96/311 reads (31%) | catalogued as rs151202823; called by muse, mutect2, varscan2
- ZNF235 | c.1752A>G p.S584= | Silent (SNP) | VAF 42/128 reads (33%) | called by muse, mutect2, varscan2
- ZNF462 | c.3372G>T p.R1124= | Silent (SNP) | VAF 34/150 reads (23%) | catalogued as rs1426311219; called by muse, mutect2, varscan2
- ZNF93 | c.1776A>T p.P592= | Silent (SNP) | VAF 26/79 reads (33%) | called by muse, mutect2, varscan2
- ACO2 | c.835+74C>T | Intron (SNP) | VAF 14/124 reads (11%) | catalogued as rs778076233; called by muse, mutect2
- CCDC74A | c.250+84A>G | Intron (SNP) | VAF 44/222 reads (20%) | called by muse, mutect2, varscan2
- CRYZL1 | c.799-334G>A | Intron (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- CTNND2 | c.-26G>C | 5'UTR (SNP) | VAF 12/108 reads (11%) | called by muse, mutect2, varscan2
- ESPNP | n.1259A>G | RNA (SNP) | VAF 13/56 reads (23%) | catalogued as rs1166971368; called by mutect2, varscan2
- FCRLB | c.575-255T>C | Intron (SNP) | VAF 39/365 reads (11%) | called by muse, mutect2, varscan2
- GABRA6 | c.530-47C>G | Intron (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2, varscan2
- HKDC1 | c.2373-18C>T | Intron (SNP) | VAF 18/190 reads (9%) | called by muse, mutect2
- KRT4 | c.*35C>T | 3'UTR (SNP) | VAF 32/332 reads (10%) | catalogued as rs758554468; called by muse, mutect2
- MPZL3 | c.*18C>G | 3'UTR (SNP) | VAF 42/110 reads (38%) | called by muse, mutect2, varscan2
- NIPA1 | c.317+1860G>A | Intron (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- PPP1R3A | c.-12T>G | 5'UTR (SNP) | VAF 211/355 reads (59%) | called by muse, mutect2, varscan2
- SH3TC1 | c.3131+535G>A | Intron (SNP) | VAF 21/291 reads (7%) | called by muse, mutect2
- SKOR2 | c.2753-136A>T | Intron (SNP) | VAF 20/194 reads (10%) | called by muse, mutect2
- SNX29 | c.-56C>G | 5'UTR (SNP) | VAF 5/42 reads (12%) | catalogued as rs1191938420; called by muse, mutect2
- TMEM75 | n.818A>T | RNA (SNP) | VAF 11/152 reads (7%) | called by muse, mutect2
- WBP2 | c.655+97C>T | Intron (SNP) | VAF 8/162 reads (5%) | catalogued as rs962259155; called by muse, mutect2
- ZC3HAV1 | c.1471+216C>T | Intron (SNP) | VAF 83/213 reads (39%) | catalogued as rs931265311; called by muse, mutect2, varscan2
